Somatic mutation profile of tumor specimen TCGA-TQ-A8XE-01A (aliquot TCGA-TQ-A8XE-01A-11D-A36O-08) from TCGA case TCGA-TQ-A8XE, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 42.8 years (15,629 days).
Specimen TCGA-TQ-A8XE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09059923-7c36-4ea5-ab23-5a858350c2d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A8XE-10A (Blood Derived Normal), aliquot TCGA-TQ-A8XE-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9ed62ed-f973-4acd-8d0f-8d735ef64c47

The open-access MAF lists 39 somatic variants for this specimen: 34 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 29, Silent 5, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 29/89 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 29/63 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 37/51 reads (73%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB9 | c.1697A>G p.D566G (on ENST00000280560 / NM_019625.4; = p.D523G on NM_019624.3) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99757578; called by muse, mutect2, varscan2
- ADGRG3 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs773580809, COSV100342106, COSV59652292; called by muse, mutect2, varscan2
- CDCP1 | c.175G>C p.V59L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99943874; called by muse, mutect2, varscan2
- CYP2A7 | c.1289T>C p.V430A | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99393748; called by muse, mutect2, varscan2
- DSCAML1 | c.3391C>T p.R1131W (on ENST00000321322; = p.R1071W on NM_020693.4) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs563772293, COSV100354855; called by muse, mutect2, varscan2
- EPHA5 | c.3008+1G>A p.X1003_splice | Splice Site (SNP) | VAF 24/80 reads (30%) | catalogued as COSV99896739; called by muse, mutect2, varscan2
- EPHB4 | c.2665C>G p.R889G | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.201); catalogued as rs762016655, COSV62268494, COSV62271028; called by muse, mutect2, varscan2
- FOXS1 | c.950C>A p.T317N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs769718614, COSV99639534, COSV99639661; called by muse, mutect2, varscan2
- GFRAL | c.816T>A p.S272R | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV100474701; called by muse, mutect2
- KIAA0319 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV65496399; called by muse, mutect2, varscan2
- KRT73 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs774602570, COSV59839009, COSV99988183; called by muse, mutect2, varscan2
- LCT | c.3023T>C p.V1008A | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV99928734; called by muse, mutect2, varscan2
- MSI1 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99981391; called by muse, mutect2, varscan2
- MYO3A | c.932T>C p.M311T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99778581; called by muse, mutect2, varscan2
- NEU2 | c.206A>G p.Q69R | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.147); catalogued as rs1163471769, COSV99290464; called by muse, mutect2, varscan2
- OR4C6 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.03); catalogued as COSV100051439; called by muse, mutect2, varscan2
- PCDHB5 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); catalogued as rs1554275685, COSV99167673; called by muse, mutect2, varscan2
- RTTN | c.5075T>C p.L1692P | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99731283; called by mutect2, varscan2
- SCD5 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV100124388; called by muse, mutect2, varscan2
- SIGLEC14 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as rs759989219, COSV55778956; called by muse, mutect2, varscan2
- SLC17A4 | c.190A>G p.M64V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100930519; called by muse, mutect2, varscan2
- SLC5A10 | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100524852; called by muse, mutect2, varscan2
- TIMP1 | c.76T>A p.C26S | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99512122; called by muse, mutect2, varscan2
- TMLHE | c.785A>G p.H262R | Missense Mutation (SNP) | VAF 79/282 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100544614; called by muse, mutect2, varscan2
- TMTC3 | c.1091A>G p.N364S | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99898142; called by muse, mutect2, varscan2
- TPX2 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.649); catalogued as rs762641961, COSV100301570; called by muse, mutect2
- TRMT2B | c.1168+1G>T p.X390_splice | Splice Site (SNP) | VAF 59/155 reads (38%) | catalogued as COSV100105212; called by muse, mutect2, varscan2
- TRRAP | c.1588C>G p.Q530E | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100722087; called by muse, varscan2
- RTN1 | c.2202_2206del p.L735Cfs*5 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | called by mutect2, pindel, varscan2
- SMC6 | c.2300A>G p.E767G | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- STK26 | c.1187_1215del p.T396Kfs*38 | Frame Shift Del (DEL) | VAF 18/168 reads (11%) | called by mutect2, pindel
- CDC42BPG | c.3396C>T p.R1132= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs771011142, COSV100711981; called by muse, mutect2
- EGF | c.3387T>C p.T1129= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as COSV54479704; called by muse, mutect2, varscan2
- EIF2AK3 | c.2358A>G p.E786= | Silent (SNP) | VAF 112/244 reads (46%) | catalogued as rs762928284, COSV100303516; called by muse, mutect2, varscan2
- MXRA5 | c.1968G>A p.Q656= | Silent (SNP) | VAF 47/202 reads (23%) | catalogued as COSV99475993; called by muse, mutect2, varscan2
- SYT9 | c.1260C>T p.N420= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs758629936, COSV59615734; called by muse, mutect2, varscan2
